Somatic mutation profile of tumor specimen MMRF_1079_1_BM_CD138pos (aliquot MMRF_1079_1_BM_CD138pos_T1_KHS5U_L14261) from MMRF case MMRF_1079, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_1079_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 847598c3-89fa-40d3-ac98-0bf5ab89e388.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1079_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1079_2_PB_WBC_C3_KHS5U_L14263; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcc50ba5-252c-4395-b854-cf3a5cf2598a

The open-access MAF lists 184 somatic variants for this specimen: 79 protein-altering or splice-affecting, 25 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, 3'UTR 53, Silent 25, Intron 15, Nonsense Mutation 6, 3'Flank 5, Frame Shift Del 4, 5'UTR 3, 5'Flank 3, Splice Site 3, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8A | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.604); catalogued as rs757222387; called by muse, mutect2, varscan2
- CBFB | c.165+1G>C p.X55_splice | Splice Site (SNP) | VAF 27/28 reads (96%) | catalogued as COSV51996680, COSV51997241, COSV51997594, COSV52002060; called by muse, mutect2, varscan2
- CHL1 | c.1153G>A p.E385K (on ENST00000397491 / NM_001253387.1; = p.E401K on NM_006614.4) | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV56610975; called by muse, mutect2
- COL6A2 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 109/216 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as rs757488307, COSV100153473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2W1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as rs887927083; called by muse, mutect2
- D2HGDH | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.065); catalogued as rs746956176, CM101392; called by muse, mutect2, varscan2
- DAPK3 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 35/326 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs774146708; called by muse, mutect2, varscan2
- GEMIN6 | c.126C>T p.A42= | Splice Region (SNP) | VAF 125/264 reads (47%) | catalogued as rs779727449; called by muse, mutect2, varscan2
- GTPBP4 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1473578919; called by muse, mutect2, varscan2
- HOXC13 | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778468919; called by muse, mutect2
- IGHV2-70 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372581706; called by muse, mutect2, varscan2
- IGHV2-70 | c.53T>A p.L18* | Nonsense Mutation (SNP) | VAF 47/106 reads (44%) | catalogued as rs546731210; called by muse, varscan2
- IGHV2-70 | c.52T>G p.L18V | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs543742874; called by muse, varscan2
- IGHV4-34 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs587753421; called by muse, mutect2, varscan2
- IGKJ4 | c.36A>C p.K12N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | PolyPhen possibly damaging (0.548); catalogued as rs78964890; called by muse, varscan2
- IGKV4-1 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775128716; called by muse, mutect2, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- IRAK1BP1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 361/522 reads (69%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV64047994; called by muse, mutect2, varscan2
- KIF17 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs371219583, COSV56118638; called by muse, mutect2, varscan2
- KLK14 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs367549276; called by muse, mutect2, varscan2
- LRRC8E | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs372027576; called by muse, mutect2, varscan2
- MEGF8 | c.7960G>A p.V2654I (on ENST00000251268 / NM_001271938.2; = p.V2587I on NM_001410.3) | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs373377277; called by muse, mutect2
- MEOX2 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100012269; called by muse, mutect2, varscan2
- MYO5A | c.4559C>T p.A1520V | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV62558447, COSV62561434; called by muse, mutect2, varscan2
- MYO7A | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145544778, CM138857; called by muse, mutect2
- PI4KA | c.4518G>A p.W1506* | Nonsense Mutation (SNP) | VAF 23/269 reads (9%) | catalogued as rs1441862473; called by muse, mutect2
- PIEZO2 | c.6542C>T p.P2181L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs192092641; called by muse, mutect2, varscan2
- SAMSN1 | c.208dup p.M70Nfs*14 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | catalogued as rs760167411; called by mutect2, varscan2
- SERPINB8 | c.424+1G>A p.X142_splice | Splice Site (SNP) | VAF 13/118 reads (11%) | catalogued as COSV99039546; called by muse, mutect2, varscan2
- SPTBN4 | c.4313C>T p.P1438L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.1); catalogued as COSV58946849; called by muse, mutect2, varscan2
- TLL2 | c.1850A>G p.E617G | Missense Mutation (SNP) | VAF 126/257 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779804858; called by muse, mutect2, varscan2
- WDR81 | c.2782G>A p.V928M | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs191700184; called by muse, mutect2, varscan2
- ZNF268 | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.056); catalogued as rs1335119330; called by muse, mutect2
- ANKRD9 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANO9 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2
- CEP162 | c.1684C>T p.L562F | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); called by muse, mutect2
- CHMP7 | c.260T>G p.V87G | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COPG1 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CYLD | c.1839del p.F613Lfs*18 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- CYLD | c.2408dup p.Y803* | Nonsense Mutation (INS) | VAF 30/126 reads (24%) | called by mutect2, pindel, varscan2
- DSC3 | c.1805C>A p.P602H | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2
- DSG2 | c.3076A>T p.S1026C | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- DYNC2LI1 | c.59A>C p.N20T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ELP1 | c.2939C>T p.P980L | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FNBP1 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FRMD3 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSIP2 | c.19834G>C p.A6612P | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GULP1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 192/439 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC7 | c.1453C>T p.Q485* (on ENST00000427332; = p.Q524* on NM_015401.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- HMCN2 | c.14587+4A>G | Splice Region (SNP) | VAF 17/223 reads (8%) | called by muse, mutect2
- HOXC11 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH8 | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KCNK7 | c.679C>A p.H227N | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNN4 | c.938A>G p.E313G | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2
- KLK1 | c.47-1G>C p.X16_splice | Splice Site (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- LRRK2 | c.7265A>G p.N2422S | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MUC17 | c.9424G>T p.A3142S | Missense Mutation (SNP) | VAF 118/1161 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MUSK | c.2086C>G p.P696A | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NOTCH2 | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE5A | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 111/233 reads (48%) | called by muse, mutect2, varscan2
- PKHD1 | c.11547G>C p.L3849F | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPP4R3C | c.2026G>T p.E676* | Nonsense Mutation (SNP) | VAF 65/67 reads (97%) | called by muse, mutect2, varscan2
- PRDM1 | c.2122_2143del p.G708Rfs*9 | Frame Shift Del (DEL) | VAF 29/191 reads (15%) | called by mutect2, pindel
- PSD3 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 130/261 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RB1 | c.32_63del p.A11Gfs*9 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- RYR2 | c.5407A>G p.S1803G | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SENP7 | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SHANK1 | c.955C>A p.H319N | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SPATA17 | c.1042T>C p.S348P | Missense Mutation (SNP) | VAF 107/287 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SV2B | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.071); called by muse, mutect2
- SYNPR | c.538G>C p.V180L | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM202 | c.563A>C p.D188A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTC6 | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TTK | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TYRP1 | c.200del p.A67Efs*2 | Frame Shift Del (DEL) | VAF 168/330 reads (51%) | called by mutect2, pindel, varscan2
- UBE2M | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2
- VWA2 | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 23/390 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- WDR35 | c.2017G>T p.D673Y (on ENST00000345530 / NM_001006657.2; = p.D662Y on NM_020779.4) | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF813 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 153/491 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ACOT7 | c.1032G>A p.V344= (on ENST00000377855 / NM_181864.3; = p.V334= on NM_007274.4) | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- ANGPTL4 | c.454C>T p.L152= | Silent (SNP) | VAF 96/274 reads (35%) | called by muse, mutect2, varscan2
- ANKRD9 | c.438C>T p.R146= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as rs1304020991; called by muse, mutect2, varscan2
- ARHGAP44 | c.1458G>A p.E486= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as rs1348502020; called by muse, mutect2
- DOP1A | c.363G>A p.V121= | Silent (SNP) | VAF 24/282 reads (9%) | called by muse, mutect2
- DROSHA | c.3681G>A p.A1227= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs368252147, COSV60777735; called by muse, mutect2, varscan2
- FAM83C | c.186G>A p.R62= | Silent (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.135A>G p.G45= | Silent (SNP) | VAF 120/230 reads (52%) | catalogued as rs770658990; called by muse, varscan2
- IKBKB | c.2007C>T p.V669= | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- LINGO1 | c.213C>T p.T71= | Silent (SNP) | VAF 69/581 reads (12%) | catalogued as rs754883713; called by muse, mutect2, varscan2
- MANEAL | c.909G>A p.A303= (on ENST00000373045 / NM_001113482.1; = p.A81= on NM_152496.2) | Silent (SNP) | VAF 226/383 reads (59%) | catalogued as rs779950563, COSV61116465; called by muse, mutect2, varscan2
- NPY4R | c.417G>A p.R139= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs782361775; called by muse, mutect2, varscan2
- NR2F1 | c.1014G>A p.A338= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as rs201229023; called by muse, mutect2, varscan2
- OR5H1 | c.585T>C p.N195= | Silent (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- PBDC1 | c.213T>A p.I71= | Silent (SNP) | VAF 38/130 reads (29%) | called by muse, mutect2, varscan2
- PLXDC2 | c.462G>T p.R154= | Silent (SNP) | VAF 109/221 reads (49%) | called by muse, mutect2, varscan2
- RBM25 | c.522A>G p.A174= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- RELB | c.1105C>T p.L369= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as rs777367214; called by muse, mutect2, varscan2
- RGS3 | c.2082G>A p.E694= (on ENST00000350696 / NM_001282923.2; = p.E413= on NM_130795.4) | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV100637112; called by muse, mutect2
- RIPOR3 | c.642C>T p.Y214= | Silent (SNP) | VAF 65/109 reads (60%) | catalogued as rs149203288; called by muse, mutect2, varscan2
- SCRN2 | c.918C>T p.T306= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs185581282, COSV51634814; called by muse, mutect2, varscan2
- SV2B | c.144C>T p.G48= | Silent (SNP) | VAF 60/342 reads (18%) | catalogued as rs773245122, COSV57699882; called by muse, mutect2, varscan2
- SYNE1 | c.9915A>G p.S3305= (on ENST00000367255 / NM_182961.4; = p.S3312= on NM_033071.3) | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as rs764114386; ClinVar: likely benign; called by muse, mutect2, varscan2
- UMAD1 | c.51A>C p.P17= | Silent (SNP) | VAF 89/324 reads (27%) | called by muse, mutect2, varscan2
- WT1 | c.393G>A p.P131= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs1229890218; called by muse, mutect2, varscan2
- ABCA8 | c.797+173G>T | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, varscan2
- ABR | c.700+368G>A | Intron (SNP) | VAF 11/49 reads (22%) | catalogued as rs989088226; called by muse, mutect2, varscan2
- AC004947.2 | chr7:26534680 C>T | 5'Flank (SNP) | VAF 16/327 reads (5%) | called by muse, mutect2
- ADH6 | chr4:99203535 G>A | 3'Flank (SNP) | VAF 29/77 reads (38%) | catalogued as rs569961609; called by muse, mutect2, varscan2
- BTN1A1 | c.*931C>T | 3'UTR (SNP) | VAF 152/477 reads (32%) | called by muse, mutect2, varscan2
- C1orf43 | c.*723A>G | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+2678T>C | Intron (SNP) | VAF 38/160 reads (24%) | called by muse, mutect2, varscan2
- CD226 | c.*2547T>C | 3'UTR (SNP) | VAF 6/91 reads (7%) | catalogued as rs1263339231; called by muse, mutect2
- CDH19 | c.*3584G>T | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- CUX1 | c.*1257C>A | 3'UTR (SNP) | VAF 44/464 reads (9%) | called by muse, mutect2
- CUX1 | c.*2667C>T | 3'UTR (SNP) | VAF 19/202 reads (9%) | called by muse, mutect2
- DNAJC11 | c.*903C>T | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- EFCAB1 | c.*847G>T | 3'UTR (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2
- ERC1 | c.*2621C>A | 3'UTR (SNP) | VAF 41/142 reads (29%) | called by muse, mutect2, varscan2
- ERP27 | c.*593A>C | 3'UTR (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- FBXO33 | c.*1056A>T | 3'UTR (SNP) | VAF 10/16 reads (63%) | called by muse, varscan2
- FYTTD1 | c.*1740G>A | 3'UTR (SNP) | VAF 10/128 reads (8%) | catalogued as rs563261808; called by muse, mutect2
- GM2A | c.*2245A>G | 3'UTR (SNP) | VAF 82/625 reads (13%) | called by muse, mutect2, varscan2
- GRIA4 | c.247+1662A>C | Intron (SNP) | VAF 35/46 reads (76%) | called by muse, mutect2, varscan2
- HDLBP | c.*1322A>G | 3'UTR (SNP) | VAF 52/221 reads (24%) | catalogued as rs1043171681; called by muse, mutect2, varscan2
- HOXA3 | chr7:27106804 C>T | 3'Flank (SNP) | VAF 61/172 reads (35%) | catalogued as rs1487130594; called by muse, mutect2, varscan2
- HPS3 | c.*869T>G | 3'UTR (SNP) | VAF 120/279 reads (43%) | called by muse, mutect2, varscan2
- IGHM | chr14:105859484 G>C | 5'Flank (SNP) | VAF 10/10 reads (100%) | catalogued as rs1276693169; called by muse, varscan2
- IGHM | chr14:105859495 C>G | 5'Flank (SNP) | VAF 10/11 reads (91%) | called by muse, varscan2
- IL1R1 | c.*241T>C | 3'UTR (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- IPO9 | c.*5384C>T | 3'UTR (SNP) | VAF 13/172 reads (8%) | catalogued as rs934951215; called by muse, mutect2
- ITGB1 | c.2331+1197T>C | Intron (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2
- ITPK1 | c.*636G>T | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- JAZF1 | c.*1278del | 3'UTR (DEL) | VAF 17/173 reads (10%) | called by mutect2, pindel, varscan2
- JPH4 | c.*283A>T | 3'UTR (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- KCTD8 | c.-156_-127del | 5'UTR (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel
- LHX5 | c.*333C>G | 3'UTR (SNP) | VAF 3/35 reads (9%) | catalogued as rs1335349856; called by muse, mutect2
- LRP10 | c.*713C>T | 3'UTR (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- MAX | c.295+334G>T | Intron (SNP) | VAF 62/316 reads (20%) | called by muse, mutect2, varscan2
- MED23 | c.*456A>G | 3'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- MMP16 | c.*7G>T | 3'UTR (SNP) | VAF 114/258 reads (44%) | catalogued as COSV99685868, COSV99689285; called by muse, mutect2, varscan2
- MRAP2 | c.*867T>G | 3'UTR (SNP) | VAF 14/248 reads (6%) | called by muse, mutect2
- MTMR1 | c.1656+236G>A | Intron (SNP) | VAF 292/293 reads (100%) | called by muse, mutect2, varscan2
- MTR | c.*2775del | 3'UTR (DEL) | VAF 7/81 reads (9%) | catalogued as rs1329907125; called by pindel, varscan2
- MYO19 | c.*572A>C | 3'UTR (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- NEK7 | c.*2439T>C | 3'UTR (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- NFIB | c.*4272G>T | 3'UTR (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- NISCH | c.1528+1129C>T | Intron (SNP) | VAF 52/153 reads (34%) | called by muse, mutect2, varscan2
- NNMT | c.*167T>C | 3'UTR (SNP) | VAF 21/269 reads (8%) | called by muse, mutect2
- NUP50 | c.*2905T>G | 3'UTR (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- OR2C3 | c.*213T>G | 3'UTR (SNP) | VAF 34/132 reads (26%) | called by muse, mutect2, varscan2
- OSBPL3 | c.*510T>C | 3'UTR (SNP) | VAF 56/103 reads (54%) | called by muse, mutect2, varscan2
- PAFAH1B2 | c.*2039A>G | 3'UTR (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- PALLD | c.1501+8739T>A | Intron (SNP) | VAF 30/156 reads (19%) | called by muse, varscan2
- PARVA | c.*1094C>T | 3'UTR (SNP) | VAF 61/87 reads (70%) | catalogued as rs1345894851; called by muse, mutect2, varscan2
- PHF20L1 | c.*514G>A | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- PIK3CG | c.*1286T>C | 3'UTR (SNP) | VAF 32/42 reads (76%) | called by muse, mutect2, varscan2
- PM20D2 | c.*248del | 3'UTR (DEL) | VAF 7/44 reads (16%) | called by mutect2, varscan2
- PPP4R4 | c.*514G>A | 3'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as COSV56229343; called by muse, mutect2, varscan2
- PRKRIP1 | c.*593G>A | 3'UTR (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- PRLR | c.*7052G>C | 3'UTR (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- PTPRD | c.541+298T>C | Intron (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82979499 G>C | 3'Flank (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- REG4 | c.*215C>A | 3'UTR (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- RREB1 | c.707+11G>C | Intron (SNP) | VAF 63/233 reads (27%) | called by muse, mutect2, varscan2
- RSBN1 | c.*1681T>C | 3'UTR (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- RUBCN | c.*3356C>T | 3'UTR (SNP) | VAF 79/167 reads (47%) | called by muse, mutect2, varscan2
- SEMA6D | c.1765+40T>C | Intron (SNP) | VAF 47/666 reads (7%) | called by muse, mutect2
- SLC5A9 | c.*75C>A | 3'UTR (SNP) | VAF 38/294 reads (13%) | called by muse, mutect2, varscan2
- SMARCB1 | c.*28G>A | 3'UTR (SNP) | VAF 15/208 reads (7%) | called by muse, mutect2
- SNORD115-13 | n.67G>A | RNA (SNP) | VAF 19/393 reads (5%) | called by muse, mutect2
- SPICE1 | c.*2235C>T | 3'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- SRC | c.*481C>T | 3'UTR (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- STARD8 | c.-156G>A | 5'UTR (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- SUPT5H | c.*27G>A | 3'UTR (SNP) | VAF 73/117 reads (62%) | catalogued as rs771750800; called by muse, mutect2, varscan2
- SV2A | c.*400G>T | 3'UTR (SNP) | VAF 12/237 reads (5%) | called by muse, mutect2
- TCF21 | c.*9-572T>C | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- TGDS | c.*598T>A | 3'UTR (SNP) | VAF 12/12 reads (100%) | catalogued as rs1012283243; called by muse, varscan2
- TLE6 | c.702+54T>C | Intron (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- TMEM170B | c.*5459C>T | 3'UTR (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- TPD52L2 | c.-19G>A | 5'UTR (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- TRIM29 | c.1135-23A>T | Intron (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- URM1 | chr9:128392762 C>A | 3'Flank (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- WWC1 | c.*2171C>T | 3'UTR (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- ZNF721 | chr4:438593 C>T | 3'Flank (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
